Gene-level copy-number profile of tumor specimen TCGA-78-7536-01A from TCGA case TCGA-78-7536, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 70.0 years (25,558 days).
Specimen TCGA-78-7536-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.e42d985e-e1ec-47e1-9d46-954453b66f43.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-78-7536-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/85740060-bfa9-4c25-a5fa-53db4d13c093

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 2,900; copy number 2: 21,702; copy number 3: 18,729; copy number 4: 10,642; copy number 5: 2,989; copy number 6: 1,975; copy number 7: 391; copy number 8: 234; copy number 9: 112; copy number 11: 35; copy number 18: 35; copy number 47: 32.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-78-7536-01A-11D-2062-01): tumor purity 0.78, ploidy 3.04, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:78,161,698–81,953,534, 26 genes: RN7SKP61, AC108752.1, MRPS17P3, ROBO1, AC055731.1, RN7SL751P, AC117461.1, MIR3923, HMGB1P38, OSBPL9P1, HNRNPA3P8, AC108740.1, AC108690.1, AC068756.1, LINC02050, LINC02027, AC099542.2, AC099542.1, AC107302.2, AC107302.1, GBE1, RNU2-28P, SETP6, AC017015.1, AC017015.2, AC129807.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,803 genes in 51 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,963,954–5,090,899, 3 genes, copy number 5: BX005132.1, LINC02781, LINC02782.
- chr1:228,555,793–229,508,341, 41 genes, copy number 5: RNA5SP19, RNA5SP162, RNA5S1, RNA5S2, RNA5S3, RNA5S4, RNA5S5, RNA5S6, RNA5S7, RNA5S8, RNA5S9, RNA5S10, RNA5S11, RNA5S12, RNA5S13, RNA5S14, RNA5S15, RNA5S16, RNA5S17, RNA5SP18, DUSP5P1, AL713899.1, FTH1P2, RHOU, AL078624.2, AL078624.1, LINC02815, ISCA1P2, LINC02814, AL162595.2, TMEM78, AL162595.1, RAB4A, AL117350.1, CCSAP, RNU6-180P, RN7SKP276, AL160004.2, ACTA1, NUP133, AL160004.1.
- chr1:237,471,119–240,776,824, 49 genes, copy number 5: MIR4428, AL442065.1, AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8.
- chr2:4,628,216–6,003,510, 13 genes, copy number 5: LINC01249, AC092169.1, RNU6-649P, AC073143.1, AC107057.1, LINC01248, AC108025.1, SOX11, AC010729.2, AC010729.1, LINC01810, SILC1, MIR7158.
- chr2:49,563,388–52,961,452, 26 genes, copy number 5 (within-gene range 4–5): AC009971.1, RPL7P13, SNORA75, NRXN1, AC068725.1, MTCO1P42, AC009234.1, MIR8485, AC007560.1, AC007682.1, AC007402.1, AC007402.2, KNOP1P3, CRYGGP, AC097463.1, CCDC12P1, AC079304.1, ZNF863P, Y_RNA, LINC01867, GGCTP3, AC139712.1, CRTC1P1, FTH1P6, MIR4431, AC010967.1.
- chr2:119,439,843–120,223,400, 17 genes, copy number 5 (within-gene range 3–5): SCTR, SCTR-AS1, CFAP221, TMEM177, RPL17P15, PTPN4, RPL27P7, EPB41L5, AC012363.1, Y_RNA, MTATP6P26, MTCO3P43, MTND3P10, MTND4LP14, MTND4P26, MTND5P28, TMEM185B.
- chr2:134,028,608–134,918,710, 12 genes, copy number 5–6 (within-gene range 3–6): AC092623.1, MGAT5, MIR3679, RNA5SP104, EDDM3CP, TMEM163, AC110620.2, CCNT2-AS1, VDAC2P4, AC110620.1, ACMSD, MIR5590.
- chr2:153,158,938–155,664,668, 29 genes, copy number 5: ATP5PBP4, AC011901.1, AC079150.1, LINC01850, RPL23AP29, TUBAP13, AC012501.2, AC012501.1, RPRM, DNAJA1P2, GALNT13, PHBP4, AC009227.1, AC009227.2, RNA5SP107, AC061961.1, KCNJ3, CBX3P6, AC092625.1, RNU6-1001P, MTCO1P45, MTND2P20, ATP5F1AP2, MTND4P28, MTND5P30, MTND6P9, MTCYBP9, RNU6-546P, AC073225.1.
- chr2:180,571,712–195,737,702, 173 genes, copy number 5–18 (within-gene range 3–18) (broad region; genes not listed).
- chr2:199,760,544–209,182,018, 240 genes, copy number 6–11 (broad region; genes not listed).
- chr2:238,412,642–240,080,362, 32 genes, copy number 47: RNU6-234P, ASB1, AC016999.1, AC016999.2, LINC01107, LINC01937, AC113618.2, AC113618.1, AC145625.2, AC145625.1, TWIST2, LINC01940, HDAC4, MIR4440, MIR4441, AC017028.1, AC017028.2, MIR4269, MIR2467, HDAC4-AS1, AC023787.2, AC023787.3, AC023787.1, AC079612.1, AC079612.2, AC093802.2, AC093802.1, NDUFA10, MIR4786, OR6B2, OR6B3, OR9S24P.
- chr3:116,360,024–117,997,592, 16 genes, copy number 6 (within-gene range 4–6): LSAMP-AS1, LINC00903, RN7SL582P, BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8, RNU6-1200P, AC092691.1, AC092691.2, LINC02024, AC092691.3.
- chr3:133,015,004–166,721,610, 513 genes, copy number 6–7 (broad region; genes not listed).
- chr5:2,712,591–5,078,311, 28 genes, copy number 6: LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063, AC106799.3, AC106799.2, AC106799.1, AC010634.1, LINC02114, AC026719.1, AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121.
- chr5:10,652,211–23,689,386, 150 genes, copy number 5–9 (broad region; genes not listed).
- chr5:23,972,188–31,555,053, 79 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr5:33,944,623–45,895,970, 198 genes, copy number 5–6 (broad region; genes not listed).
- chr6:167,607–17,707,344, 315 genes, copy number 5 (broad region; genes not listed).
- chr7:146,050,062–148,420,998, 10 genes, copy number 5 (within-gene range 4–5): AC073308.1, CNTNAP2, AC073418.1, Y_RNA, CNTNAP2-AS1, DUTP3, RANP2, MIR548F4, AC005518.1, AC005518.2.
- chr7:157,987,169–158,591,696, 6 genes, copy number 5: AC011899.3, AC011899.1, MIR595, AC078942.1, LINC01022, MIR5707.
- chr8:39,106,990–99,877,580, 928 genes, copy number 6–9 (within-gene range 3–9) (broad region; genes not listed).
- chr8:100,157,906–108,083,642, 146 genes, copy number 5–6 (broad region; genes not listed).
- chr8:110,766,863–138,914,041, 318 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr8:139,460,062–141,432,454, 32 genes, copy number 5: AC087354.1, AC090093.1, KCNK9, TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3.
- chr8:142,089,827–145,066,685, 169 genes, copy number 5 (broad region; genes not listed).
- chr11:28,679,183–29,064,322, 3 genes, copy number 5 (within-gene range 4–5): LINC02758, LINC02742, OR2BH1P.
- chr11:37,702,125–41,714,492, 22 genes, copy number 5 (within-gene range 3–5): AC061997.1, RPL7AP56, LINC02760, AC103798.1, LRRC6P1, AC021713.1, LINC02759, LINC01493, AC021723.2, AC021723.1, RNU6-99P, AC021749.1, AC021820.1, AC080100.1, LRRC4C, Y_RNA, AC090720.1, RNU6-365P, AC090138.1, LINC02741, AC021006.1, AC021006.2.
- chr11:77,659,996–79,441,030, 37 genes, copy number 5 (within-gene range 3–5): RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1.
- chr12:66,767–2,697,950, 51 genes, copy number 5–6 (within-gene range 3–6): IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2, AC005342.2, LINC00940, DCP1B, CACNA1C, AC005342.1, CACNA1C-IT1, CACNA1C-IT2, AC005344.1, CACNA1C-AS4, CACNA1C-IT3, AC005293.1.
- chr12:7,470,811–8,019,007, 31 genes, copy number 5: CD163, GAPDHP31, NIFKP3, AC006927.1, AC006927.2, AC006927.4, AC006927.3, AC006927.5, APOBEC1, GDF3, DPPA3, CLEC4C, NANOGNB, Y_RNA, NANOG, Y_RNA, SLC2A14, AC006517.2, Y_RNA, Metazoa_SRP, AC006517.1, AC124891.1, NANOGP1, AC007536.1, SLC2A3, AC006511.6, Y_RNA, AC006511.1, AC006511.4, HSPD1P12, AC006511.2.
- chr12:28,978,584–29,381,189, 9 genes, copy number 5: AC024255.1, AC012150.1, FAR2, AC012150.2, AC009318.4, AC009318.1, AC009318.3, AC009318.2, ERGIC2.
- chr12:44,880,868–45,610,620, 14 genes, copy number 5 (within-gene range 4–5): Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, AC009248.3, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6.
- chr12:58,544,124–61,702,771, 25 genes, copy number 5: AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1, AC080011.1, AC087883.2, AC087883.1, Y_RNA, AC090022.1, AC090022.2, AC090017.1, DUX4L52, AC090629.1.
- chr14:25,916,015–28,418,612, 16 genes, copy number 5: AL132633.1, CYB5AP5, NOVA1, AL079343.1, LINC02588, AL110292.1, LINC02294, LINC02293, AL132718.1, MIR4307HG, MIR4307, AL390334.1, LINC00645, MIR3171, BNIP3P1, AL139023.1.
- chr14:32,879,246–39,216,335, 119 genes, copy number 5 (broad region; genes not listed).
- chr14:40,630,006–43,596,683, 22 genes, copy number 5 (within-gene range 4–5): AL390800.1, LINC02315, AL391516.1, AL356596.1, AL121821.3, AL121821.2, AL121821.1, LRFN5, FKBP1BP1, AL445074.1, AL442163.1, AL450442.1, AL442163.2, AL442163.3, YWHAQP1, AL163153.1, TUBBP3, HNRNPUP1, AL583809.1, KRT8P2, AL358913.1, ARHGAP16P.
- chr14:90,820,064–92,935,285, 38 genes, copy number 5 (within-gene range 3–5): LINC02321, RPS6KA5, DGLUCY, RNU7-30P, SNORA11B, GPR68, AL135818.1, AL135818.2, AL135818.3, CCDC88C, AL133153.2, AL133153.1, PPP4R3A, AL133373.2, AL133373.3, CATSPERB, POLR3GP1, NANOGP7, AL121839.1, U3, AL121839.2, TC2N, FBLN5, TRIP11, AL049872.1, ATXN3, NDUFB1, CPSF2, AL133240.1, RNU6-366P, AL133240.2, SLC24A4, RIN3, LGMN, GOLGA5, LINC02833, LINC02287, CHGA.
- chr14:97,427,071–103,562,831, 256 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr14:103,847,721–106,875,071, 265 genes, copy number 6 (broad region; genes not listed).
- chr20:3,777,504–64,313,132, 1,337 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,653. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
